Surgical pathology report (de-identified scan), TCGA case TCGA-21-5783, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-5783-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis:
Left lung CA

Source of Specimen(s):
A: Portion of 6th rib
B: Lymph Node, level 9
C: Lymph Node, level 11
D: Left lung
E: Lymph Node, level 5
F: Lymph Node, level 7

Gross Description:
The specimen is received in six parts.

Source of Tissue: 1. Labeled "portion 6th rib".

Gross Description: Received fresh and consists of a segment of rib measuring 2 x 1.4 x 1cm. No gross suspicious lesions are found. It is submitted entirely in 1A following decalcification.

Designation of Sections: 1A

Summary of Sections: @

Source of Tissue: 2. Labeled "level 9 lymph node".

Gross Description: Received fresh and consists of a single grayish-black lymph node measuring 0.9 x 0.7 x 0.7cm. It is submitted entirely in 2A.

Designation of Sections: 2A

Summary of Sections: @

Source of Tissue: 3. Labeled "level 11 lymph node".

Gross Description: Received fresh and consists of an irregular, ragged fragment of black tissue measuring 1.5 x 1 x 0.7cm. It is submitted intoto in 3A.

Designation of Sections: 3A

Summary of Sections: @

Source of Tissue: 4. Labeled "left lung (left upper lobe)".

Frozen Section Diagnosis: 4FS HISTOLOGICALLY NEGATIVE MARGIN, BUT GROSSLY ONLY BY 3-4MM, PER [REDACTED]

Gross Description: The specimen is received fresh and consists of a 235 gram left upper lobe measuring 18 x 11 x 6.5cm. The bronchial margin is procured for frozen section consultation and submitted in 4FSA.

[page 2 of 3]
The bronchial tree is opened to reveal lesional tissue approximately 0.2 0.3cm from the margin (4C). Elsewhere, vascular margins are unremarkable and the hilum contains a few black, anthracotic nodes. Sections show multiple potential peribronchial nodes with metastatic (4D-4E).

Laterally, there is a large area of pleural puckering up to 3cm and sections show a large 7 x 6 x 5cm tumor comprising approximately 40% of the left upper lobe. Centrally, the tumor has some black discoloration is necrotic, however, towards the periphery there is more grossly viable tumor.

Sections through the remaining parenchyma show pink, spongy lung tissue with black, anthracotic pigmentation. No other suspicious lesions or masses are found.

Designation of Sections: 4FSA bronchial margin, 4A vascular margin, 4B hilar nodes, 4C section approximately 5cm from bronchial margin, 4D-4E additional section hilum, possible peribronchial lymph nodes, 4F-4G tumor, 4H tumor in relationship to left pleura, 4I uninvolved lung tissue.

Summary of Sections: Representative section 4FSA, 4A 4I.

Source of Tissue: 5. Labeled "level 5 lymph node".

Gross Description: The specimen is received fresh and consists of two gray-black node fragments measuring 0.3 and 0.5cm. and consists of fat. It is submitted in 5A.

Designation of Sections: 5A

Summary of Sections: @

Source of Tissue: 6. Labeled "Level 7 lymph node".

Gross Description: Received fresh the specimen consists of a single, ovoid, black lymph node measuring 0.9 x 0.9 x 0.6cm and submitted in toto in 6A.

Designation of Sections: 6A

Summary of Sections: @

Final Diagnosis:

1. Portion of 6th rib, excision:
- Bone marrow elements. No tumor seen.
2. Lymph nodes, level 9, excision:
- No tumor seen in one lymph node (0/1).
3. Lymph node, level 11, excision:
- No tumor seen in one lymph node (0/1).

[page 3 of 3]
4. Left lung, upper lobe, lobectomy:

- Poorly differentiated squamous cell carcinoma (7 cm), with neuroendocrine features, see note.
- Negative bronchial and vascular margins.
- Negative pleura.
- No tumor seen in six hilar lymph nodes.

5. Lymph nodes, level 5, excision:

- No tumor seen in two lymph nodes (0/2).

6. Lymph node, level 7, excision:

- No tumor seen in one lymph node (0/1).

Note: Immunohistochemical stains show that the tumor is negative for chromogranin and synaptophysin and focally positive for CD56.

Source: NCI Genomic Data Commons file 6df44d61-ed09-4d6f-9ca1-92f743dacbb5 (TCGA-21-5783.83EB92FC-A1F0-4FEA-A7C4-3254E98735AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).